Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A28X, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A28X-01A (Primary Tumor).

FINAL DIAGNOSIS

Collection Date: _____

PART 1: LYMPH NODE, CENTRAL COMPARTMENT, SELECTIVE DISSECTION

- A. METASTATIC CARCINOMA IN TWO OUT OF SIX LYMPH NODES (2/6).
- B. NO EXTRANODAL EXTENSION.

PART 2: THYROID, TOTAL THYROIDECTOMY (17 GRAMS)

- A. PAPILLARY THYROID CARCINOMA, TWO FOCI (1.2 CM AND 0.5 CM).
- B. LARGEST FOCUS: LEFT LOBE, TALL CELL VARIANT WITH EXTRATHYROID EXTENSION; TUMOR LESS THAN 0.1 CM FROM THE MARGIN.
- C. CHRONIC LYMPHOCYTIC THYROIDITIS.
- D. TWO LYMPH NODES, NO TUMOR PRESENT (0/2).
- E. PATHOLOGIC STAGE: pT3a N1.

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Thyroid cancer

PROCEDURE: Total thyroidectomy

SPECIFIC CLINICAL QUESTION: Not answered

OUTSIDE TISSUE DIAGNOSIS: Not answered

PRIOR MALIGNANCY: Not answered

CHEMORADIATION THERAPY: Not answered

ORGAN TRANSPLANT: Not answered

IMMUNOSUPPRESSION: Not answered

OTHER DISEASES: Not answered

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE:

Total Thyroidectomy

TUMOR SITE:

? Right Lobe, Left Lobe

TUMOR FOCALITY:

Multifocal

TUMOR SIZE (largest nodule):

Greatest Dimension: 1.2 cm

HISTOLOGIC TYPE**:

Papillary carcinoma

TNM DESCRIPTORS:

m

PRIMARY TUMOR (pT):

pT3

REGIONAL LYMPH NODES (pN):

pN1a

Number of regional lymph nodes examined: 6

Number of regional lymph nodes involved: 2

EXTRANODAL EXTENSION:

Not identified

DISTANT METASTASIS (pM):

Not applicable

EXTRATHYROIDAL EXTENSION:

Present

MARGINS:

Margins uninvolved by carcinoma

Distance of invasive carcinoma to closest margin: 0.1 mm

LYMPH-VASCULAR INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS:

Other: CHRONIC LYMPHOCYTIC THYROIDITIS

ICD-0-3
Carcinoma, papillary, tall cell
variant
8344/3
Site: thyroid, NOS C73.9

lw
5/25/11

Diagnostic Discrepancy		X

Source: NCI Genomic Data Commons file 5e046e78-9e5b-4268-b3e4-09dcadc8e807 (TCGA-BJ-A28X.BECBC693-AC81-4094-8833-28189B8BF8C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).